Surgical pathology report (de-identified scan), TCGA case TCGA-KQ-A41R, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Cornell Medical College, specimen TCGA-KQ-A41R-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Laboratory

ical Pathology Report

IN LAB DATE:

Report Date:

Submitted by:

10003

path: urothelial carcinoma, papillary 8/30/13

QCF: urothelial carcinoma, NOS 8/20/13

Site: path: bladder, NOS C67.9

Telephone:

7.25.12
RD QCF: bladder, wall, NOS C67.9

Location:

CLINICAL INFORMATION:

Bladder cancer. Robotic partial cystectomy, right ureteral stent placement.

Specimen submitted: A. Right pelvic lymph nodes; B. Bladder diverticulum

DIAGNOSIS:

A. Lymph nodes, pelvic, right (excision):

Two lymph nodes, negative for metastatic carcinoma (0/2).

B. Bladder (partial cystectomy):

High grade papillary urothelial carcinoma of bladder diverticulum, with invasion of underlying smooth muscle. (stage pT2)

Surgical resection margins appear free of tumor.

Para-ovarian adhesions.

Multiple coelomic inclusion cysts of ovary.

Atrophy of Fallopian tube.

Hydatid of Morgagni.

GROSS DESCRIPTION:

A. Received fresh, the specimen is labeled "right pelvic lymph node," and consists of an aggregate of adipose tissue and lymph nodes measuring 2.4 x 1.9 x 1.0 cm. The specimen is entirely submitted. Summary of sections: A1-A3.

B. Received fresh, the specimen is labeled "bladder diverticulum," and consists of a dilated diverticulum measuring 4.0 x 3.0 x 3.0 cm. The diverticulum contains a 3.2 x 2.0 x 1.4 cm polypoid, papillary, friable tan mass. There is an adjacent bladder cuff margin measuring 1.5 x 1.0 cm which is inked black and entirely submitted perpendicularly. The tumor is 0.8 cm from the bladder cuff margin and 2.5 cm from the soft tissue margin. Adherent to the diverticulum is a fallopian tube measuring 5.3 x 0.4 cm with fimbriated end and an ovary measuring 2.4 x 1.5 x 0.7 cm. The cortical surface of the ovary contains multiple cysts measuring up to 0.6 cm. The ovary is entirely submitted. Representative sections are submitted. Summary of sections: B1-B6-- bladder cuff margin entirely submitted perpendicularly; B7-B10-- representative tumor including soft tissue margin; B11-- entire fimbriated end of fallopian tube; B12-- paratubal cysts; B13-B16-- entire ovary.

*** Electronically Signed Out ***

Attending Pathologist

The attending pathologist whose signature appears on this report has reviewed the diagnostic slides, and has edited the gross and microscopic portions of the report in rendering the final diagnosis.

[page 2 of 2]
Slides: A-3, B-16

Source: NCI Genomic Data Commons file 384435f4-80f6-42e3-8939-202fb6681f0b (TCGA-KQ-A41R.D54B3725-D134-4F18-9FFC-8074F8942BC6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).